TCGA case TCGA-AX-A0IS — Uterine Corpus Endometrial Carcinoma (TCGA-UCEC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Corpus uteri; Tissue source site: Gynecologic Oncology Group. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2e5cf721-90b1-4470-b430-f055a1297c7f

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 52 years; Vital status: Dead; Days to death: 1,858 days (5.1 years).

Diagnoses (2)
1. Endometrioid adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8380/3; ICD-10 code: C54.1; Tissue or organ of origin: Endometrium; Site of resection or biopsy: Endometrium; Classification of tumor: primary; Age at diagnosis: 52.5 years (19,173 days); Year of diagnosis: 2008; Method of diagnosis: Biopsy; FIGO stage: Stage IC; FIGO staging edition year: 1988; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Days to last follow up: 1,858 days (5.1 years).
   Pathology details: Consistent pathology review: Yes; Percent tumor invasion: 50.
   Pathology details: Lymph node involved site: Aortic; Lymph nodes positive: 0; Lymph nodes tested: 4.
   Pathology details: Lymph node involved site: Pelvis, NOS; Lymph nodes positive: 0; Lymph nodes tested: 10.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Days to treatment start: 13 days; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Brivanib; Initial disease status: Progressive Disease; Days to treatment start: 513 days (1.4 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Doxorubicin; Initial disease status: Progressive Disease; Days to treatment start: 583 days (1.6 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Tivozanib; Initial disease status: Progressive Disease; Days to treatment start: 1,065 days (2.9 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Gemcitabine Hydrochloride; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Surgery, Minimally Invasive; Initial disease status: Initial Diagnosis.
   Recorded, whether given is unknown: Pharmaceutical Therapy, NOS (Tamoxifen), prior to diagnosis.
2. Diagnosis record without a diagnosis name: Age at diagnosis: 53.7 years (19,621 days); Days to diagnosis: 448 days (1.2 years); Prior treatment: Yes.
   Recorded as not given: Surgery, NOS.

Follow-up (5 entries)
- Day 448 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 1,065 days (2.9 years); Disease response: With Tumor.
- Days to follow up: 1,858 days (5.1 years); Disease response: With Tumor.
- Peritoneal washing results: Negative; Timepoint: Initial Diagnosis.
- Follow-up contact recording only the day: day 1,541.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 132 kg; Height: 168 cm; BMI: 46.8.
- Timepoint category: Prior to Diagnosis; Menopause status: Postmenopausal; Risk factors: Diabetes, NOS / Hypertension.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AX-A0IS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 90 mg.
  Slide TCGA-AX-A0IS-01A-01-BSA: Section location: Bottom; Percent tumor cells: 83; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 15; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-AX-A0IS-01A-01-TSA: Section location: Top; Percent tumor cells: 77; Percent tumor nuclei: 80; Percent normal cells: 10; Percent necrosis: 3; Percent stromal cells: 10; Percent lymphocyte infiltration: 8; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 1.
- Sample TCGA-AX-A0IS-10B: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); History neoadjuvant treatment: No; Tumor status: With tumor; Submitted tumor site: Endometrial; Histologic diagnosis: Endometrioid endometrial adenocarcinoma; Method initial path diagnosis: Other method, specify:; Method initial path diagnosis other: Endocervical Biopsy; Surgical approach at diagnosis: Minimally Invasive.
- Follow-up form 1: Hypertension diagnosis: Yes; Diabetes diagnosis indicator: Yes; History colorectal cancer: No; Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor; New tumor event surgery: No.
- Follow-up form 2: Lost to follow-up: No; New tumor event diagnosis indicator: No.
- Follow-up form 3: Lost to follow-up: No; Tumor status: With tumor.
- Drug treatment 1: Regimen number: 4; Therapy regimen: Progression.
- Drug treatment 2: Regimen number: 2; Pharmaceutical therapy drug name: Gemzar; Therapy regimen: Recurrence.
- Drug treatment 3: Regimen number: 5; Therapy regimen: Progression.
- Drug treatment 4: Regimen number: 1.
- Drug treatment 5: Regimen number: 3; Therapy regimen: Progression.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,858 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,858 days; disease-free interval: event (new tumor event after initially disease-free), 448 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 448 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-AX-A0IS-01): tumor purity 0.84, ploidy 2.13, whole-genome doublings 0 (call status: maf_call).
